Somatic mutation profile of tumor specimen HTMCP-03-06-02363-01A (aliquot HTMCP-03-06-02363-01A-01D-9392) from CGCI case HTMCP-03-06-02363, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIA; Tumor grade: G2.
Specimen HTMCP-03-06-02363-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6eedf10-b01d-48a9-b1ed-676a302139c9.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02363-10A (Blood Derived Normal), aliquot HTMCP-03-06-02363-10A-01D-9392; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b96bd16f-d718-4cf7-8a9d-75892f0a22f6

The open-access MAF lists 51 somatic variants for this specimen: 36 protein-altering or splice-affecting, 10 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 10, Intron 5, Nonsense Mutation 4, Splice Region 2, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD6 | c.5620G>A p.E1874K | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.427); catalogued as rs760741699; called by muse, mutect2, varscan2
- COL4A1 | c.3671C>T p.P1224L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs775810147, COSV101010949; called by muse, mutect2, varscan2
- CTNNB1 | c.274C>T p.Q92* | Nonsense Mutation (SNP) | VAF 33/53 reads (62%) | catalogued as COSV62713130; called by muse, mutect2, varscan2
- DHPS | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as rs769575305, COSV52953502; called by muse, mutect2, varscan2
- DNAH2 | c.11042G>A p.R3681H | Missense Mutation (SNP) | VAF 61/107 reads (57%) | SIFT tolerated (0.05); PolyPhen benign (0.097); catalogued as rs146051088; called by muse, mutect2, varscan2
- FBN1 | c.1666G>A p.V556M | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as rs1239988676, COSV57325199; called by muse, mutect2, varscan2
- HYDIN | c.7634G>A p.R2545Q | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.69); PolyPhen benign (0.028); catalogued as rs1488307375; called by muse, mutect2, varscan2
- ICE1 | c.5777C>A p.S1926Y | Missense Mutation (SNP) | VAF 82/341 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV99664161; called by muse, mutect2, varscan2
- JAKMIP3 | c.2001C>T p.A667= | Splice Region (SNP) | VAF 5/26 reads (19%) | catalogued as rs747548875, COSV99037214; called by muse, mutect2, varscan2
- KIAA1549 | c.4344C>T p.S1448= | Splice Region (SNP) | VAF 5/18 reads (28%) | catalogued as rs766807541; called by muse, mutect2, varscan2
- MAP3K5 | c.3613C>T p.Q1205* | Nonsense Mutation (SNP) | VAF 29/96 reads (30%) | catalogued as COSV100753061; called by muse, mutect2, varscan2
- MTCL1 | c.1930G>A p.E644K (on ENST00000306329 / NM_001378206.1; = p.E284K on NM_015210.4) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750981932; called by muse, mutect2, varscan2
- PCDHGA10 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99540060; called by muse, mutect2, varscan2
- PTPRD | c.4300G>A p.E1434K | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV61932965, COSV61935427; called by muse, mutect2, varscan2
- SREBF1 | c.3373C>T p.R1125C | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV55392493; called by muse, mutect2, varscan2
- TMEM132C | c.431G>T p.R144L | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV70670204; called by muse, mutect2, varscan2
- TTN | c.92749C>T p.R30917W (on ENST00000591111; = p.R23493W on NM_003319.4) | Missense Mutation (SNP) | VAF 117/138 reads (85%) | PolyPhen probably damaging (0.999); catalogued as rs727505090; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD30A | c.2833C>G p.Q945E (on ENST00000611781; = p.Q889E on NM_052997.2) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.82); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- C16orf96 | c.1995G>T p.Q665H | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- CARMIL1 | c.979C>T p.Q327* | Nonsense Mutation (SNP) | VAF 22/110 reads (20%) | called by muse, mutect2, varscan2
- CLEC14A | c.1421G>C p.R474T | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- CNTRL | c.5220dup p.E1741Rfs*22 | Frame Shift Ins (INS) | VAF 19/60 reads (32%) | called by mutect2, pindel, varscan2
- DNAJC1 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DYNC2H1 | c.3925C>T p.L1309F | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HFM1 | c.1683G>C p.Q561H | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- LRRK2 | c.3839A>G p.E1280G | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MAGI3 | c.692G>C p.R231T | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- PDZD7 | c.1361C>T p.S454F | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRDM2 | c.3511_3519del p.F1171_D1173del | In Frame Del (DEL) | VAF 76/239 reads (32%) | called by mutect2, pindel, varscan2
- PSD | c.1993C>T p.H665Y | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ROCK2 | c.1039G>T p.E347* | Nonsense Mutation (SNP) | VAF 39/69 reads (57%) | called by muse, mutect2, varscan2
- SCNN1G | c.1571T>C p.I524T | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- YEATS2 | c.484G>C p.E162Q | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- ZKSCAN2 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF292 | c.1576G>C p.E526Q | Missense Mutation (SNP) | VAF 105/119 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- ZNF397 | c.846G>C p.E282D | Missense Mutation (SNP) | VAF 91/160 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ANKRD62 | c.424C>T p.L142= | Silent (SNP) | VAF 33/130 reads (25%) | catalogued as rs756030100; called by muse, mutect2, varscan2
- COL12A1 | c.2217C>T p.F739= | Silent (SNP) | VAF 14/33 reads (42%) | called by muse, mutect2, varscan2
- DNAH11 | c.7959A>C p.A2653= | Silent (SNP) | VAF 128/211 reads (61%) | called by muse, mutect2, varscan2
- FARP2 | c.105C>A p.L35= | Silent (SNP) | VAF 82/94 reads (87%) | called by muse, mutect2, varscan2
- FAT3 | c.12498C>T p.F4166= | Silent (SNP) | VAF 14/30 reads (47%) | called by mutect2, varscan2
- JARID2 | c.2391C>G p.V797= | Silent (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2, varscan2
- SDHA | c.1215C>T p.T405= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as rs762888704; ClinVar: likely benign; called by muse, mutect2, varscan2
- TSC2 | c.909C>T p.L303= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs1433197017, CD015383; called by muse, mutect2, varscan2
- TSNAXIP1 | c.564C>T p.L188= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV99534767; called by mutect2, varscan2
- WDR62 | c.3384C>G p.L1128= | Silent (SNP) | VAF 18/70 reads (26%) | called by muse, mutect2, varscan2
- ANK1 | c.5619+245G>C | Intron (SNP) | VAF 16/72 reads (22%) | catalogued as rs200742602; called by muse, mutect2, varscan2
- CDC42BPB | c.3811+486C>T | Intron (SNP) | VAF 17/73 reads (23%) | called by muse, mutect2, varscan2
- CFAP65 | c.2211+93C>T | Intron (SNP) | VAF 25/33 reads (76%) | catalogued as rs1460358901; called by muse, mutect2, varscan2
- ROBO2 | c.3761-2345C>T | Intron (SNP) | VAF 13/46 reads (28%) | catalogued as rs1402361669; called by muse, mutect2, varscan2
- SPINK5 | c.475-442G>A | Intron (SNP) | VAF 16/41 reads (39%) | called by muse, mutect2, varscan2
